Surgical pathology report (de-identified scan), TCGA case TCGA-43-6143, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-6143-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SPECIMEN

- A. Medial lobe lymph node
- B. Right lower lobe
- C. Level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer.

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labeled "middle lobe lymph node" are three red-black irregular soft tissue fragments which have an aggregate measurement of 0.6 x 0.3 x 0.2 cm. [REDACTED] specimens are entirely submitted in one cassette. AS-1.

[REDACTED] Received fresh subsequently fixed in formalin labeled "right lower lobe" is a crepitant lobe of lung which is 20 x 14 x 8 cm. This has a red violaceous smooth glistening pleura with diffuse black stippling present. There is an umbilication measuring 1.5 x 1.5 cm. along side the bronchial margin. This is heavily stapled. The staples are removed. There is a 0.9 cm. black lymph node grossly identified in the hilum. The area of the umbilication is inked and the specimen is sectioned to show a 4.5 x 4.5 x 4.0 cm. gray pink tan well-circumscribed lesion. This is contiguous with the umbilication and comes within 3.0 cm. of bronchial margin. The remainder of the cut surface of the specimen is pink tan black and spongy showing no other discrete gross lesions identified. Representative sections of the specimen are submitted as follows: block 1 - bronchial and vascular margins; block 2 - possible hilar node; block 3 and 4 - tumor to umbilication and hilum; block 5 - representative s [REDACTED] of tumor to normal; block 6 - representative normal. RS-6.

C. Received fresh label [REDACTED] el 7" are eight soft gray-black-red tissues measuring up to [REDACTED] 8 cm in greatest dimension which are submitted in toto. AS-1. [REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Invasive squamous cell carcinoma with prominent basaloid features.

Histologic grade: Moderately-differentiated

Primary tumor (pT): Carcinoma is 4.5 cm in greatest dimension.

Margins of resection: Negative.

Direct extension of tumor: Negative.

Venous (large vessel) invasion: Negative.

Arterial (large vessel) invasion: Negative.

Lymphatic (small vessel) invasion: Negative.

Regional lymph nodes (pN): Three negative middle lobe lymph node fragments.

One negative hilar lymph node. Eight negative level 7 lymph node fragments.

Other findings: Background lung parenchyma shows respiratory bronchiolitis.

This case receive [REDACTED]

[REDACTED]

[page 2 of 2]
[REDACTED]

"The tumor displays a distinctive basaloid morphology with focal areas of squamoid differentiation and keratinization. Like you, we considered the diagnosis of small cell carcinoma given the focal molding and hyperchromatic nuclei with scant cytoplasm; however, given the evidence of squamous differentiation (p63 and CK5/6 staining) and lack of demonstrable neuroendocrine differentiation, I favor the diagnosis of squamous cell carcinoma with basaloid features."

Immunoperoxidase staining was performed on paraffin sections at the referring institution (CD56, CK5/6, chromogranin, synaptophysin, TTF-1 and p63) and reviewed at [REDACTED]. The neoplastic cells are strongly reactive with CK5/6, with focal CD56 reactivity, but not reactive with TTF-1, synaptophysin and chromogranin."

5, 4x2, 20x6

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

DIAGNOSIS

- A. Lymph node, middle lobe, biopsy:
- Three negative lymph node fragments.
- B. Lung, right lower lobe, lobectomy:
- Invasive squamous cell carcinoma with prominent basaloid features.
- Size, 4.5 cm in greatest dimension.
- Negative margins of excision.
- One negative hilar lymph node.
- C. Lymph node, level 7, regional resection:
- Seven negative lymph node fragments.
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 553410e3-a327-4536-adac-676c1932ea3e (TCGA-43-6143.0A88E8AD-53BB-4450-8131-F7AC7C79960A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).